Somatic mutation profile of tumor specimen C3L-01054-04 (aliquot CPT0123990009_1) from CPTAC case C3L-01054, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 38.4 years (14,036 days).
Specimen C3L-01054-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1af17fda-80c0-4ae0-a79e-2bb361478494.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01054-31 (Blood Derived Normal), aliquot CPT0124920002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/becbe7ac-08ee-4bca-822d-530bce944126

The open-access MAF lists 46 somatic variants for this specimen: 35 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 8, Intron 2, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C10orf71 | c.4027G>A p.V1343M | Missense Mutation (SNP) | VAF 13/450 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.494); catalogued as rs906410500, COSV60510676; called by muse, mutect2
- COL21A1 | c.2774G>T p.G925V | Missense Mutation (SNP) | VAF 18/410 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55174596, COSV99777457; called by muse, mutect2
- CR2 | c.206A>T p.D69V | Missense Mutation (SNP) | VAF 24/717 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100889492; called by muse, mutect2
- EIF2AK3 | c.2896G>T p.E966* | Nonsense Mutation (SNP) | VAF 22/600 reads (4%) | catalogued as COSV57550227; called by muse, mutect2
- EPB41L1 | c.1349C>T p.P450L | Missense Mutation (SNP) | VAF 34/746 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99150106; called by muse, mutect2
- FLNC | c.7087G>C p.D2363H | Missense Mutation (SNP) | VAF 38/1106 reads (3%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV100368390; called by muse, mutect2
- FYB1 | c.653A>G p.N218S | Missense Mutation (SNP) | VAF 18/554 reads (3%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV60942015; called by muse, mutect2
- IRF3 | c.533A>G p.N178S | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1049794743; called by muse, mutect2
- OR14A16 | c.80T>A p.I27N | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV62926150; called by muse, mutect2
- RAB39B | c.379C>G p.L127V | Missense Mutation (SNP) | VAF 10/239 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV65624745; called by muse, mutect2
- RELN | c.2263C>T p.R755C | Missense Mutation (SNP) | VAF 34/844 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58992959; called by muse, mutect2
- SCAF1 | c.181C>T p.H61Y | Missense Mutation (SNP) | VAF 28/750 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.143); catalogued as rs1461226673; called by muse, mutect2
- SLX4 | c.1991C>T p.P664L | Missense Mutation (SNP) | VAF 38/976 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369805557; called by muse, mutect2
- TFAP2C | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.764); catalogued as rs1568753299, COSV52371122; called by muse, mutect2
- ARHGEF16 | c.1144G>C p.V382L | Missense Mutation (SNP) | VAF 10/239 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.05); called by muse, mutect2
- C2orf69 | c.703G>T p.V235L | Missense Mutation (SNP) | VAF 20/542 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.02); called by muse, mutect2
- CHRM5 | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 24/540 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.323); called by muse, mutect2
- DENND1C | c.430T>C p.S144P | Missense Mutation (SNP) | VAF 11/267 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2
- EFR3B | c.1684G>T p.V562L | Missense Mutation (SNP) | VAF 13/417 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2
- ERVMER34-1 | c.580A>T p.T194S | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.031); called by muse, mutect2
- FAM117A | c.1073C>G p.P358R | Missense Mutation (SNP) | VAF 23/646 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.731); called by muse, mutect2
- GRIK2 | c.1962C>A p.N654K | Missense Mutation (SNP) | VAF 32/898 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HS3ST1 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.272); called by muse, mutect2
- LEPROT | c.7G>A p.G3S | Missense Mutation (SNP) | VAF 22/623 reads (4%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); called by muse, mutect2
- NAV2 | c.4505G>C p.S1502T (on ENST00000396087 / NM_001244963.2; = p.S1479T on NM_145117.5) | Missense Mutation (SNP) | VAF 16/426 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.582); called by muse, mutect2
- NDUFS1 | c.385C>G p.P129A | Missense Mutation (SNP) | VAF 28/820 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NGF | c.574A>C p.I192L | Missense Mutation (SNP) | VAF 15/417 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); called by muse, mutect2
- PGR | c.2366T>A p.M789K | Missense Mutation (SNP) | VAF 26/674 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.099); called by muse, mutect2
- PLCH1 | c.2491A>T p.S831C (on ENST00000340059 / NM_001130960.2; = p.S843C on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLEC | c.3154C>A p.R1052S (on ENST00000322810 / NM_201380.4; = p.R942S on NM_000445.5) | Missense Mutation (SNP) | VAF 12/305 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.391); called by muse, mutect2
- RYR1 | c.448C>T p.H150Y | Missense Mutation (SNP) | VAF 26/982 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SEMG2 | c.804C>A p.H268Q | Missense Mutation (SNP) | VAF 39/409 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.707); called by muse, mutect2
- SUPT3H | c.202A>T p.T68S (on ENST00000371460 / NM_181356.3; = p.T57S on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/255 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- UPB1 | c.200G>A p.R67K | Missense Mutation (SNP) | VAF 47/571 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by muse, mutect2
- ZC2HC1C | c.686G>A p.R229K | Missense Mutation (SNP) | VAF 18/630 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.232); called by muse, mutect2
- ABCC12 | c.1977C>A p.T659= | Silent (SNP) | VAF 10/221 reads (5%) | called by muse, mutect2
- CTNND1 | c.2796A>T p.T932= (on ENST00000399050 / NM_001085458.2; = p.T905= on NM_001331.3) | Silent (SNP) | VAF 12/280 reads (4%) | called by muse, mutect2
- EFHD2 | c.141G>A p.A47= | Silent (SNP) | VAF 20/473 reads (4%) | called by muse, mutect2
- IRAG1 | c.2433G>A p.E811= | Silent (SNP) | VAF 16/430 reads (4%) | catalogued as rs1440756561; called by muse, mutect2
- MYO18B | c.7605T>A p.G2535= | Silent (SNP) | VAF 24/516 reads (5%) | called by muse, mutect2
- PLIN4 | c.27G>C p.G9= (on ENST00000301286; = p.G24= on NM_001367868.2) | Silent (SNP) | VAF 10/318 reads (3%) | called by muse, mutect2
- SKIDA1 | c.1341C>A p.S447= | Silent (SNP) | VAF 13/450 reads (3%) | called by muse, mutect2
- UQCC1 | c.45T>G p.S15= | Silent (SNP) | VAF 54/581 reads (9%) | called by muse, mutect2
- MAP4K4 | chr2:101892964 C>G | 3'Flank (SNP) | VAF 12/224 reads (5%) | called by muse, mutect2
- PITX2 | c.185-965C>T | Intron (SNP) | VAF 36/970 reads (4%) | called by muse, mutect2
- TBCE | c.1302+21C>A | Intron (SNP) | VAF 88/724 reads (12%) | called by muse, mutect2, varscan2
